Somatic mutation profile of tumor specimen C3N-03007-02 (aliquot CPT0226570013) from CPTAC case C3N-03007, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 59.6 years (21,772 days).
Specimen C3N-03007-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 85df5184-3fd1-4b42-8051-a7d6dce133fd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03007-31 (Blood Derived Normal), aliquot CPT0226590002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8ab33fdb-f605-4a92-92ff-f81ccc9808b4

The open-access MAF lists 46 somatic variants for this specimen: 33 protein-altering or splice-affecting, 8 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 8, Intron 3, Nonsense Mutation 2, Frame Shift Del 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 34/220 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MGA | c.3724C>T p.R1242* | Nonsense Mutation (SNP) | VAF 8/168 reads (5%) | hotspot (GDC flag); catalogued as COSV54948051; called by muse, mutect2
- TP53 | c.706T>C p.Y236H | Missense Mutation (SNP) | VAF 32/304 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs587782289, CM1411658, COSV52672888, COSV52675514, COSV52783032; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- BCOR | c.2531C>T p.P844L | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.049); catalogued as rs140780988; called by muse, mutect2, varscan2
- BNC1 | c.1135G>A p.V379I | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1415662180, COSV61756473; called by muse, mutect2, varscan2
- CACNA1B | c.5227C>T p.R1743C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs370345897; called by muse, mutect2
- CDHR2 | c.71C>T p.P24L | Missense Mutation (SNP) | VAF 13/220 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1171897795; called by muse, mutect2
- CSMD2 | c.2434C>T p.R812W | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1339621969, COSV99589914; called by muse, mutect2
- CTSG | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 33/413 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as rs1273091559, COSV53535447, COSV53536639; called by muse, mutect2
- MC3R | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs770261378, CM074934, COSV54763303, COSV54763474; called by muse, mutect2
- PCDHGA1 | c.2044G>A p.A682T | Missense Mutation (SNP) | VAF 48/554 reads (9%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.009); catalogued as COSV65298235; called by muse, mutect2
- RYR1 | c.4066G>A p.A1356T | Missense Mutation (SNP) | VAF 26/246 reads (11%) | SIFT tolerated (0.7); PolyPhen benign (0.012); catalogued as rs933347966, COSV100614977; called by mutect2, varscan2
- SLC6A15 | c.2050G>A p.E684K | Missense Mutation (SNP) | VAF 9/84 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as rs1006033978, COSV57019783; called by muse, mutect2, varscan2
- SPTBN5 | c.5426G>A p.R1809H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as rs757454069; called by muse, mutect2, varscan2
- TIAM1 | c.1637G>A p.C546Y | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99734315; called by muse, mutect2
- VASN | c.952G>A p.V318I | Missense Mutation (SNP) | VAF 24/292 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as rs755829190, COSV52030715; called by muse, mutect2
- WDR35 | c.3001A>T p.T1001S (on ENST00000345530 / NM_001006657.2; = p.T990S on NM_020779.4) | Missense Mutation (SNP) | VAF 32/346 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV55606399; called by muse, mutect2
- ADAMTS1 | c.890G>A p.S297N | Missense Mutation (SNP) | VAF 25/404 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ASB1 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 63/403 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- CDKN2A | c.233_234del p.L78Hfs*41 | Frame Shift Del (DEL) | VAF 54/532 reads (10%) | called by pindel, varscan2
- ERICH1 | c.19C>T p.H7Y | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.549); called by muse, mutect2
- FAM184B | c.2572C>A p.R858S | Missense Mutation (SNP) | VAF 25/267 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); called by muse, mutect2
- KIAA1210 | c.3889C>T p.L1297F | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.171); called by muse, mutect2
- LHX8 | c.381T>G p.D127E | Missense Mutation (SNP) | VAF 10/208 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2
- OR51B2 | c.135C>A p.Y45* | Nonsense Mutation (SNP) | VAF 14/200 reads (7%) | called by muse, mutect2
- PGF | c.581G>T p.G194V | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); called by mutect2, varscan2
- RAB2A | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 7/195 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.09); called by muse, mutect2
- RASSF6 | c.653A>G p.Y218C (on ENST00000342081 / NM_201431.2; = p.Y186C on NM_177532.5) | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- THBS2 | c.161C>A p.A54D | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); called by muse, mutect2
- TRPS1 | c.1110G>T p.E370D (on ENST00000220888 / NM_001330599.2; = p.E383D on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/290 reads (5%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2
- TTLL6 | c.1625A>G p.K542R (on ENST00000393382 / NM_001130918.3; = p.K235R on NM_173623.3) | Missense Mutation (SNP) | VAF 21/271 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.16); called by muse, mutect2
- ZC2HC1B | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2
- ZZZ3 | c.1813A>G p.K605E | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.028); called by muse, mutect2
- ACSS2 | c.1101C>T p.Y367= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as rs747790024, COSV53627601; called by muse, mutect2, varscan2
- CHAF1B | c.1020C>T p.Y340= | Silent (SNP) | VAF 14/171 reads (8%) | catalogued as rs370336150; called by muse, mutect2
- F2 | c.777G>A p.E259= | Silent (SNP) | VAF 30/368 reads (8%) | called by muse, mutect2
- MAVS | c.1293G>A p.P431= | Silent (SNP) | VAF 23/280 reads (8%) | catalogued as rs546826199; called by muse, mutect2
- RADIL | c.2949C>T p.P983= | Silent (SNP) | VAF 28/294 reads (10%) | catalogued as COSV101271323; called by muse, mutect2
- SLC12A8 | c.111G>A p.V37= | Silent (SNP) | VAF 12/200 reads (6%) | called by muse, mutect2
- TNXB | c.11550C>T p.D3850= (on ENST00000647633; = p.D3603= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/1535 reads (3%) | catalogued as rs139430697; called by muse, mutect2
- ZNF667 | c.1284A>G p.A428= | Silent (SNP) | VAF 8/168 reads (5%) | called by muse, mutect2
- CCM2 | c.803+49G>A | Intron (SNP) | VAF 46/308 reads (15%) | catalogued as rs757745342, COSV51847223; called by muse, mutect2, varscan2
- CDYL2 | c.617-6447T>G | Intron (SNP) | VAF 14/230 reads (6%) | called by muse, mutect2
- RNA5-8SP2 | chr16:34159896 G>A | 5'Flank (SNP) | VAF 8/88 reads (9%) | catalogued as rs1413811503; called by muse, mutect2
- TMEM135 | c.*5024C>T | 3'UTR (SNP) | VAF 18/308 reads (6%) | catalogued as rs1390101623; called by muse, mutect2
- WDR97 | c.2426+66G>A | Intron (SNP) | VAF 26/448 reads (6%) | catalogued as rs544209807; called by muse, mutect2
